Somatic mutation profile of tumor specimen MP2PRT-PATJPX-TMP1-A (aliquot MP2PRT-PATJPX-TMP1-A-1-0-D-A81Y-36) from MP2PRT case MP2PRT-PATJPX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.3 years (1,208 days).
Specimen MP2PRT-PATJPX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 06525a84-8f32-4668-9f3a-eb2077e851cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATJPX-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATJPX-NM1-A-1-0-D-A83O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b0d5651d-fb8d-4b8e-be42-d7c50326e3a6

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 10, Silent 4, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BTNL3 | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 43/266 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs201534771, COSV61565707, COSV61566065; called by muse, mutect2, varscan2
- DNAH7 | c.11026G>A p.D3676N | Missense Mutation (SNP) | VAF 19/248 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs746243860, COSV100418192; called by muse, mutect2
- EED | c.923A>G p.Y308C | Missense Mutation (SNP) | VAF 11/154 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54556403; called by muse, mutect2
- FLT3 | c.1988A>G p.K663R | Missense Mutation (SNP) | VAF 22/397 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV54044253; called by muse, mutect2
- PADI4 | c.1180C>T p.R394* | Nonsense Mutation (SNP) | VAF 44/269 reads (16%) | catalogued as rs769999262; called by muse, mutect2, varscan2
- PER2 | c.1420G>A p.V474I | Missense Mutation (SNP) | VAF 55/313 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs372278249; called by muse, mutect2, varscan2
- TENM2 | c.6724C>T p.R2242C (on ENST00000518659 / NM_001122679.2; = p.R2003C on NM_001080428.3) | Missense Mutation (SNP) | VAF 22/428 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777269622, COSV101317975, COSV69122800; called by muse, mutect2
- HECTD4 | c.10675A>T p.T3559S | Missense Mutation (SNP) | VAF 76/372 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.007); called by mutect2, varscan2
- OR13C5 | c.550G>A p.V184I | Missense Mutation (SNP) | VAF 17/281 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.381); called by muse, mutect2
- SLC4A3 | c.3136C>A p.L1046I | Missense Mutation (SNP) | VAF 122/504 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- TRANK1 | c.6546G>A p.M2182I | Missense Mutation (SNP) | VAF 78/338 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CHD1 | c.507G>A p.E169= | Silent (SNP) | VAF 34/211 reads (16%) | called by muse, mutect2, varscan2
- DNAH12 | c.6336C>T p.A2112= (on ENST00000351747; = p.A2131= on NM_001366028.2) | Silent (SNP) | VAF 11/283 reads (4%) | catalogued as rs781924309; called by muse, mutect2
- DTNA | c.870G>A p.T290= | Silent (SNP) | VAF 43/246 reads (17%) | catalogued as rs758023465; called by muse, mutect2, varscan2
- PLCB3 | c.3261C>T p.N1087= | Silent (SNP) | VAF 38/231 reads (16%) | catalogued as rs763193027; called by muse, mutect2, varscan2
